Gene-level copy-number profile of tumor specimen C3N-00852-01 from CPTAC case C3N-00852, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.2 years (22,718 days).
Specimen C3N-00852-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5109cab5-68cb-4085-8b01-6789cd7ab5dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00852-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/c08edd6d-2c5d-4c26-8fc8-9739247fe116

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 1; copy number 2: 13; copy number 3: 4,541; copy number 4: 11,426; copy number 5: 18,862; copy number 6: 14,389; copy number 7: 4,901; copy number 8: 3,038; copy number 9: 862; copy number 10: 336; copy number 11: 29.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–4): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:118,758,211–119,637,199, 20 genes, copy number 11 (within-gene range 7–11): RNU7-34P, AC093206.1, DTWD2, PTMAP2, MIR1244-2, AC008629.1, RNU6-373P, AC008629.2, AC008629.3, DMXL1, AC118465.1, LAMTOR3P2, RNU6-701P, MIR5706, TNFAIP8, RN7SL174P, RNA5SP190, HSD17B4, AC010409.1, FABP5P6.
- chr5:120,337,549–121,060,953, 8 genes, copy number 11: RNU6-718P, AC113418.1, PRR16, PRELID3BP8, RNU4-69P, AC114284.1, AC008565.1, AC113352.1.
- chr5:121,195,980–121,196,210, 1 gene, copy number 11: AC010350.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
